Somatic mutation profile of tumor specimen ALCH-B2MB-TTP1-A (aliquot ALCH-B2MB-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2MB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.9 years (23,325 days).
Specimen ALCH-B2MB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51d9426b-dc19-4aa0-b2ce-0fdc16a50901.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2MB-NB1-A (Blood Derived Normal), aliquot ALCH-B2MB-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0404d04-9c5a-491a-878b-8e320a5f6cea

The open-access MAF lists 580 somatic variants for this specimen: 395 protein-altering or splice-affecting, 129 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 340, Silent 129, Intron 25, Nonsense Mutation 20, Frame Shift Del 13, Splice Site 12, 5'UTR 9, RNA 7, 3'UTR 7, Splice Region 7, 5'Flank 5, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLI3 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 212/978 reads (22%) | catalogued as rs121917713, CM050628, COSV67894397; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 134/438 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 115/717 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.284); catalogued as rs778857027; called by muse, mutect2, varscan2
- ABCF2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 72/447 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as rs142063362; called by muse, mutect2, varscan2
- ABCG8 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV55393214; called by muse, mutect2, varscan2
- ACOXL | c.1159C>T p.R387W (on ENST00000389811 / NM_001371254.1; = p.R357W on NM_001142807.4) | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs561949547; called by muse, mutect2, varscan2
- AL713999.2 | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 68/293 reads (23%) | catalogued as rs745435486; called by muse, mutect2, varscan2
- ALDH16A1 | c.495del p.M166Wfs*3 | Frame Shift Del (DEL) | VAF 42/245 reads (17%) | catalogued as COSV53193065; called by mutect2, pindel, varscan2
- AMPH | c.263A>T p.D88V | Missense Mutation (SNP) | VAF 102/483 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57742223; called by muse, mutect2, varscan2
- ANKRD30B | c.2738C>A p.P913H | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs1488865994, COSV57702262, COSV99080464; called by muse, mutect2
- APBA1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs1402557230; called by muse, mutect2, varscan2
- BAZ2B | c.3627G>C p.Q1209H | Missense Mutation (SNP) | VAF 109/436 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99681034; called by muse, mutect2, varscan2
- BRINP3 | c.2047C>A p.L683M | Missense Mutation (SNP) | VAF 80/361 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100819615, COSV66513180; called by muse, mutect2, varscan2
- CACNA1H | c.5116G>T p.A1706S | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.398); catalogued as COSV61988129, COSV61999777; called by muse, mutect2, varscan2
- CACNA2D1 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 130/629 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62392130; called by muse, mutect2, varscan2
- CAPN10 | c.1289G>C p.R430P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as COSV54376066; called by muse, mutect2, varscan2
- CARMIL3 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs148337730; called by muse, mutect2, varscan2
- CBY1 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as rs1423977192, COSV53263995; called by muse, mutect2, varscan2
- CCDC113 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV54685372, COSV54685921; called by muse, mutect2, varscan2
- CD1B | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100939268; called by muse, mutect2, varscan2
- CD1B | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs770791244; called by muse, mutect2, varscan2
- CEP152 | c.5024G>A p.S1675N (on ENST00000380950 / NM_001194998.2; = p.S1619N on NM_014985.4) | Missense Mutation (SNP) | VAF 190/414 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as rs757723374; called by muse, mutect2, varscan2
- CLUL1 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 88/378 reads (23%) | catalogued as COSV58111689; called by muse, mutect2, varscan2
- CNTN6 | c.562C>G p.P188A | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.824); catalogued as rs769615424; called by muse, mutect2, varscan2
- COBL | c.2023G>T p.D675Y | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs748960468, COSV54358135; called by muse, mutect2, varscan2
- CPS1 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 106/480 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756595148; called by muse, mutect2, varscan2
- CRISPLD2 | c.915G>A p.R305= | Splice Region (SNP) | VAF 64/263 reads (24%) | catalogued as rs370539314; called by muse, mutect2, varscan2
- CUBN | c.9976C>A p.Q3326K | Missense Mutation (SNP) | VAF 80/418 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs888688797; called by muse, mutect2, varscan2
- CYFIP1 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.145); catalogued as rs370773976; called by muse, mutect2
- DCAF5 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as rs993256471; called by muse, mutect2, varscan2
- DLG2 | c.2443C>G p.Q815E | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs1450154852; called by muse, mutect2, varscan2
- DNAAF5 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 82/453 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs760002404, COSV52418068; called by muse, mutect2, varscan2
- DNAH11 | c.6295G>A p.D2099N | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750251384, COSV60980953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP10 | c.2004del p.F668Lfs*13 | Frame Shift Del (DEL) | VAF 24/240 reads (10%) | catalogued as COSV100070826; called by mutect2, pindel
- DYSF | c.3643G>T p.A1215S | Missense Mutation (SNP) | VAF 81/369 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99250279; called by muse, mutect2, varscan2
- E2F1 | c.451G>C p.V151L | Missense Mutation (SNP) | VAF 108/686 reads (16%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.974); catalogued as COSV58535612; called by muse, mutect2, varscan2
- EHHADH | c.1550del p.G517Dfs*52 | Frame Shift Del (DEL) | VAF 35/331 reads (11%) | catalogued as COSV51628338, COSV99213143; called by mutect2, pindel, varscan2
- ESR1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.026); catalogued as rs1199270277, COSV52785552; called by muse, varscan2
- ETAA1 | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55475094; called by muse, mutect2
- EXOC3L1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs146438233, COSV52048430; called by muse, mutect2, varscan2
- EYS | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 70/417 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV60998928; called by muse, mutect2, varscan2
- FCHO1 | c.888del p.R297Gfs*11 | Frame Shift Del (DEL) | VAF 25/131 reads (19%) | catalogued as COSV53183133; called by mutect2, pindel, varscan2
- FCRL1 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 95/491 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as rs1419330960; called by muse, mutect2, varscan2
- FLT4 | c.2228C>G p.A743G | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.156); catalogued as COSV56098861; called by muse, mutect2, varscan2
- GJA10 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs1401243178; called by muse, mutect2, varscan2
- GLI4 | c.1123C>G p.R375G | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.548); catalogued as rs1422881132; called by muse, varscan2
- GOLGB1 | c.3875C>G p.S1292C | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV61465384; called by muse, mutect2, varscan2
- GRM8 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 37/154 reads (24%) | catalogued as COSV100281060; called by muse, mutect2, varscan2
- HECW1 | c.3065G>C p.R1022P | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.564); catalogued as rs562449289, COSV67825485; called by muse, mutect2, varscan2
- HLA-DQB2 | c.431G>T p.C144F | Missense Mutation (SNP) | VAF 47/454 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759100922, COSV68614333; called by muse, mutect2
- HRG | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51644559; called by muse, mutect2, varscan2
- IGLV1-47 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1357857700; called by muse, mutect2
- IGSF3 | c.1432C>T p.R478C (on ENST00000369486 / NM_001007237.3; = p.R498C on NM_001542.4) | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754026425; called by muse, mutect2, varscan2
- INSR | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.499); catalogued as rs1183440326; called by muse, mutect2
- ITGAD | c.1234C>A p.L412M | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV66760596; called by muse, mutect2, varscan2
- KCNB2 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049980; called by muse, mutect2, varscan2
- KCNH4 | c.2113C>G p.R705G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs201984974; called by muse, mutect2, varscan2
- LAIR1 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV57305865; called by muse, varscan2
- LILRB5 | c.1327C>T p.L443F (on ENST00000449561 / NM_001081442.3; = p.L442F on NM_006840.5) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.675); catalogued as rs1166072040; called by muse, mutect2, varscan2
- LRIG2 | c.1733A>G p.Y578C | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208616884; called by muse, mutect2, varscan2
- LRP2 | c.13303G>T p.V4435F | Missense Mutation (SNP) | VAF 146/675 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV55554573; called by muse, mutect2, varscan2
- MAGEA3 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 196/493 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1258965349; called by muse, mutect2, varscan2
- MAGEB6B | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 99/328 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs371855458; called by muse, mutect2, varscan2
- MBD3L3 | c.326T>A p.L109Q | Missense Mutation (SNP) | VAF 90/859 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs1192842047; called by muse, mutect2, varscan2
- MED18 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV100868934; called by muse, mutect2, varscan2
- MTNR1B | c.1025C>G p.A342G | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as CM121606, COSV57066951; called by muse, mutect2, varscan2
- MTUS2 | c.135C>A p.S45R | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.011); catalogued as COSV101462379; called by muse, mutect2, varscan2
- MUC17 | c.9118A>C p.T3040P | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.86); catalogued as rs1201892479; called by muse, mutect2, varscan2
- MUC2 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.68); catalogued as rs1403596976; called by muse, mutect2, varscan2
- MYLK3 | c.1766T>C p.M589T | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs369236002; called by muse, mutect2, varscan2
- MYO7B | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 37/356 reads (10%) | catalogued as COSV67346492; called by muse, mutect2, varscan2
- MYOD1 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV51452503; called by muse, mutect2, varscan2
- NCAPD3 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55546075; called by muse, mutect2, varscan2
- NELL1 | c.2197T>A p.L733M | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1320879974; called by muse, mutect2, varscan2
- NOTCH1 | c.5351G>T p.R1784L | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV53042678, COSV53097961; called by muse, mutect2, varscan2
- NPC1 | c.1350C>G p.I450M | Missense Mutation (SNP) | VAF 27/483 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs368945671, COSV52579864; called by muse, mutect2
- OR10Q1 | c.849C>G p.Y283* | Nonsense Mutation (SNP) | VAF 31/276 reads (11%) | catalogued as COSV57471692; called by muse, mutect2
- OR10Z1 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 74/448 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV63524803; called by muse, mutect2, varscan2
- OR4C46 | c.825G>C p.M275I | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.006); catalogued as COSV60218808; called by muse, mutect2, varscan2
- OR4S1 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100180159; called by muse, mutect2, varscan2
- OR6N1 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as COSV58647361; called by muse, mutect2, varscan2
- OR7E24 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 113/456 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs990912519, COSV71702354; called by muse, mutect2, varscan2
- PAPLN | c.899G>T p.R300L (on ENST00000554301; = p.R273L on NM_173462.4) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV53723029; called by muse, mutect2, varscan2
- PAPPA | c.505C>A p.R169S | Missense Mutation (SNP) | VAF 123/342 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60287655; called by muse, mutect2, varscan2
- PAPPA | c.506G>C p.R169P | Missense Mutation (SNP) | VAF 123/345 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60290095; called by muse, mutect2, varscan2
- PARD3 | c.2152C>T p.L718F | Missense Mutation (SNP) | VAF 72/317 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs534658969; called by muse, mutect2, varscan2
- PGBD1 | c.2005A>T p.M669L | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV52551156; called by muse, mutect2, varscan2
- PHACTR2 | c.641G>C p.R214P | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV59855756; called by muse, mutect2, varscan2
- PLCB1 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 97/549 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV62047584; called by muse, mutect2, varscan2
- PLPPR4 | c.350A>G p.Q117R | Missense Mutation (SNP) | VAF 98/417 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99058583; called by muse, mutect2, varscan2
- PMVK | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 69/424 reads (16%) | catalogued as rs1228955826; called by muse, mutect2, varscan2
- POLR3A | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 139/546 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.048); catalogued as rs1359911803; called by muse, mutect2, varscan2
- POTEH | c.447C>A p.S149R | Missense Mutation (SNP) | VAF 167/490 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs372896187; called by muse, varscan2
- POU5F2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1480345840, COSV67937345; called by muse, mutect2, varscan2
- PRPS1L1 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs951303636; called by muse, mutect2, varscan2
- PRUNE1 | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs961796484, COSV99039972; called by muse, mutect2, varscan2
- PSG5 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 112/621 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61654888; called by muse, mutect2
- PTPN14 | c.3061C>T p.R1021* | Nonsense Mutation (SNP) | VAF 69/311 reads (22%) | catalogued as rs771183448, COSV65281053; called by muse, mutect2, varscan2
- PXDN | c.1008C>G p.F336L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV53227863; called by muse, mutect2, varscan2
- RASSF9 | c.264G>C p.R88S | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63432934; called by muse, mutect2, varscan2
- RDH8 | c.165C>A p.V55= (on ENST00000651512; = p.V35= on NM_015725.4) | Splice Region (SNP) | VAF 5/31 reads (16%) | catalogued as COSV50674909, COSV50677326, COSV99408671; called by mutect2, varscan2
- RFX7 | c.2183G>C p.G728A (on ENST00000559447 / NM_001368074.1; = p.G825A on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/625 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.891); catalogued as rs757257870, COSV57962481; called by muse, mutect2, varscan2
- RGS6 | c.659G>T p.C220F | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs1393848230; called by muse, mutect2, varscan2
- SERPINA5 | c.712C>G p.R238G | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.511); catalogued as rs765037493, COSV61574431; called by muse, mutect2, varscan2
- SLC30A2 | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779896941, COSV65332443; called by muse, mutect2, varscan2
- SPEG | c.5485C>T p.R1829W | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376444717, COSV56676440; called by muse, mutect2, varscan2
- SPTA1 | c.6790G>T p.D2264Y | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV63756703, COSV63757326; called by muse, mutect2, varscan2
- SPTA1 | c.4296G>T p.L1432F | Missense Mutation (SNP) | VAF 114/726 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63751732, COSV63753642; called by muse, mutect2, varscan2
- SPTB | c.6345G>T p.P2115= | Splice Region (SNP) | VAF 125/470 reads (27%) | catalogued as COSV61552576; called by muse, mutect2, varscan2
- SUN1 | c.397C>T p.P133S (on ENST00000405266 / NM_001367651.1; = p.P83S on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/462 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1212790825; called by muse, mutect2, varscan2
- TAAR8 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs768588202, COSV51585648; called by muse, mutect2, varscan2
- TAAR8 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV51585980; called by muse, mutect2, varscan2
- TBC1D32 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51544574, COSV51551917; called by muse, mutect2
- TBC1D8 | c.2873-1G>A p.X958_splice | Splice Site (SNP) | VAF 56/214 reads (26%) | catalogued as rs1337407397; called by mutect2, varscan2
- TMEM132A | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); catalogued as rs140412965, COSV99136741; called by muse, varscan2
- TP53 | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM942119, COSV52688040, COSV52961532, COSV53198425; called by muse, mutect2, varscan2
- TRIM5 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.77); catalogued as COSV59899212, COSV99045319; called by muse, mutect2, varscan2
- TTLL4 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51438039; called by muse, varscan2
- TTN | c.65365G>T p.V21789F (on ENST00000591111; = p.V14365F on NM_003319.4) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | PolyPhen probably damaging (0.999); catalogued as rs549709481; called by muse, mutect2, varscan2
- UBQLN3 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 43/481 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1176293845; called by muse, mutect2
- ZFHX4 | c.2669G>T p.G890V | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50672991; called by muse, mutect2, varscan2
- ZNF568 | c.1808G>T p.R603M | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.921); catalogued as rs77487210; called by muse, mutect2, varscan2
- ZNF570 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.549); catalogued as COSV57579981; called by muse, mutect2, varscan2
- ZNF676 | c.824A>G p.H275R (on ENST00000650058; = p.H243R on NM_001001411.3) | Missense Mutation (SNP) | VAF 118/862 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs563924087, COSV68093471; called by muse, varscan2
- ZNF80 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV57361609; called by muse, mutect2, varscan2
- ABCA13 | c.10739G>T p.W3580L | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA7 | c.3166G>C p.G1056R | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCC9 | c.1384G>T p.V462F | Missense Mutation (SNP) | VAF 80/415 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ABCD3 | c.1845G>T p.K615N | Missense Mutation (SNP) | VAF 119/640 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ABCF3 | c.1714G>C p.V572L | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, varscan2
- ACSL4 | c.806C>T p.P269L (on ENST00000340800 / NM_022977.2; = p.P228L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/361 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ADAMTS16 | c.2273C>A p.T758N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.549); called by muse, varscan2
- ADCY1 | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG4 | c.3998C>A p.T1333N | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ADGRL3 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 139/656 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL3 | c.4031G>T p.S1344I (on ENST00000506720 / NM_001322402.2; = p.S1233I on NM_015236.6) | Missense Mutation (SNP) | VAF 66/563 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ADGRL4 | c.1222C>A p.H408N | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- AGPS | c.638-1G>C p.X213_splice | Splice Site (SNP) | VAF 52/387 reads (13%) | called by muse, mutect2, varscan2
- AGTR1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- AKAP9 | c.9788A>T p.K3263I (on ENST00000359028; = p.K3239I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/503 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ALS2 | c.3702+4G>A | Splice Region (SNP) | VAF 63/307 reads (21%) | called by muse, mutect2, varscan2
- ANKRD44 | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, varscan2
- ARHGAP11A | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 77/464 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ARHGAP23 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.2923C>G p.P975A (on ENST00000368013 / NM_001025598.2; = p.P764A on NM_181720.3) | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGEF17 | c.4696G>T p.E1566* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2
- ATM | c.4298A>T p.Y1433F | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- BAIAP2L2 | c.534G>T p.L178F | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BATF3 | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BCAT1 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BLVRA | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 159/791 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMX | c.889T>A p.F297I | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- BPIFA2 | c.408_409delinsT p.I139Sfs*8 | Frame Shift Del (DEL) | VAF 37/273 reads (14%) | called by pindel, varscan2*
- BTNL3 | c.1336del p.Q446Sfs*108 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | called by mutect2, pindel
- C1orf68 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- C20orf85 | c.131T>C p.L44S | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- C4orf54 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CACHD1 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 64/305 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CACNA1C | c.1579T>C p.Y527H | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CACNA2D2 | c.1520A>G p.N507S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- CACNB2 | c.835C>A p.P279T (on ENST00000324631 / NM_201596.3; = p.P224T on NM_000724.4) | Missense Mutation (SNP) | VAF 143/871 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMTA1 | c.2919C>A p.N973K | Missense Mutation (SNP) | VAF 76/372 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CASP5 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CCDC102B | c.1520T>A p.L507H | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CCDC58 | c.54A>G p.E18= | Splice Region (SNP) | VAF 60/224 reads (27%) | called by muse, mutect2
- CCER1 | c.783C>A p.F261L | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCR8 | c.876C>A p.H292Q | Missense Mutation (SNP) | VAF 102/330 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDADC1 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDC40 | c.1024A>T p.T342S | Missense Mutation (SNP) | VAF 117/503 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH12 | c.1649T>C p.I550T | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- CDH20 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CENPF | c.7212G>T p.E2404D | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CENPO | c.813T>A p.H271Q | Missense Mutation (SNP) | VAF 140/502 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEP72 | c.403+1del | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | called by mutect2, pindel, varscan2
- CFAP300 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.269); called by muse, varscan2
- CFAP46 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2
- CFAP47 | c.4925G>A p.G1642E | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHAT | c.1168C>A p.L390M | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CHD7 | c.6413G>A p.G2138D | Missense Mutation (SNP) | VAF 150/950 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHKA | c.351-2A>T p.X117_splice | Splice Site (SNP) | VAF 31/165 reads (19%) | called by muse, mutect2, varscan2
- CHP2 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCN2 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 153/431 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CLEC4C | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CLEC4E | c.182A>G p.E61G | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL1A2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 204/1070 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- COPS2 | c.1136A>T p.N379I | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CPTP | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 78/470 reads (17%) | called by muse, mutect2, varscan2
- CSMD3 | c.7724del p.P2575Hfs*70 (on ENST00000297405 / NM_001363185.1; = p.P2471Hfs*70 on NM_052900.3) | Frame Shift Del (DEL) | VAF 94/667 reads (14%) | called by mutect2, pindel, varscan2
- CSMD3 | c.7058T>A p.F2353Y (on ENST00000297405 / NM_001363185.1; = p.F2249Y on NM_052900.3) | Missense Mutation (SNP) | VAF 130/704 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CUBN | c.7591A>T p.N2531Y | Missense Mutation (SNP) | VAF 111/489 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- CYLC2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CYP2F1 | c.1157C>A p.T386N | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DACT1 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2
- DBF4 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DCC | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 286/706 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCSTAMP | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DCTN1 | c.3820A>G p.S1274G | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- DDX18 | c.778A>C p.T260P | Missense Mutation (SNP) | VAF 91/337 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDX18 | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 91/341 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- DDX25 | c.1225A>T p.I409F | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- DIAPH1 | c.3600C>G p.D1200E | Missense Mutation (SNP) | VAF 150/728 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH10 | c.5828G>T p.C1943F (on ENST00000409039; = p.C1882F on NM_207437.3) | Missense Mutation (SNP) | VAF 61/353 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNALI1 | c.454C>T p.Q152* (on ENST00000296218; = p.Q130* on NM_003462.5) | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- DPP4 | c.1298+1G>C p.X433_splice | Splice Site (SNP) | VAF 39/331 reads (12%) | called by muse, mutect2, varscan2
- DSC2 | c.943-2A>T p.X315_splice | Splice Site (SNP) | VAF 56/343 reads (16%) | called by muse, mutect2, varscan2
- DSG1 | c.590A>T p.K197M | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DSG1 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 78/400 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DST | c.1451A>G p.Y484C (on ENST00000361203 / NM_001374722.1; = p.Y158C on NM_001723.6) | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.2260G>T p.A754S | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- EEF1A2 | c.840T>G p.F280L | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- EGFR | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 137/696 reads (20%) | called by muse, mutect2, varscan2
- ELOA3D | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 104/866 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ERFE | c.240C>A p.D80E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- ERN2 | c.1400T>G p.L467R | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ESR1 | c.365A>T p.Q122L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, varscan2
- ETV2 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- EXOC3 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 175/547 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EXOC3 | c.892G>T p.V298F | Missense Mutation (SNP) | VAF 175/549 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FAM155B | c.786C>A p.D262E | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- FAM89A | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2
- FBN2 | c.6403G>T p.G2135C | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO4 | c.647-2A>C p.X216_splice | Splice Site (SNP) | VAF 30/200 reads (15%) | called by muse, mutect2, varscan2
- FGD5 | c.3697G>C p.G1233R | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.3603G>C p.Q1201H | Missense Mutation (SNP) | VAF 112/646 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLNA | c.6770-1G>T p.X2257_splice (on ENST00000369850 / NM_001110556.2; = p.X2249_splice on NM_001456.3) | Splice Site (SNP) | VAF 151/424 reads (36%) | called by muse, mutect2, varscan2
- FMOD | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FRAT2 | c.202G>C p.G68R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- FZD5 | c.1030del p.A344Pfs*3 | Frame Shift Del (DEL) | VAF 33/271 reads (12%) | called by mutect2, pindel, varscan2
- GAK | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- GALNT12 | c.1462T>C p.F488L | Missense Mutation (SNP) | VAF 94/471 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GALNT17 | c.230A>C p.Q77P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2
- GAR1 | c.238T>A p.C80S | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- GFPT1 | c.1602G>C p.L534F (on ENST00000357308 / NM_001244710.2; = p.L516F on NM_002056.4) | Missense Mutation (SNP) | VAF 77/424 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- GIMAP8 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 107/542 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1731G>C p.Q577H | Missense Mutation (SNP) | VAF 62/710 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by mutect2, varscan2
- GOLGA6L6 | c.1467G>T p.Q489H | Missense Mutation (SNP) | VAF 132/1872 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.524); called by muse, mutect2
- GPR32 | c.378T>A p.F126L | Missense Mutation (SNP) | VAF 89/394 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- GRM6 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- HERC2P3 | n.183G>T | Splice Region (SNP) | VAF 168/1367 reads (12%) | called by muse, mutect2, varscan2
- HEY1 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- HLTF | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 79/450 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXC13 | c.188G>C p.S63T | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HTRA4 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 102/581 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGKV1-6 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 220/1073 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGLV3-27 | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- INTS9 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- IRF2BPL | c.1153T>C p.C385R | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- IRF8 | c.554-1G>T p.X185_splice | Splice Site (SNP) | VAF 164/578 reads (28%) | called by muse, mutect2, varscan2
- ITGA6 | c.3161G>T p.W1054L (on ENST00000442250; = p.W1015L on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 183/841 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ITGAV | c.1275G>T p.W425C | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ITPRID1 | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- JAK1 | c.807A>T p.K269N | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNB2 | c.376T>G p.W126G | Missense Mutation (SNP) | VAF 74/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK12 | c.1201del p.C401Afs*19 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel, varscan2
- KCNT1 | c.383G>T p.G128V (on ENST00000488444; = p.G147V on NM_020822.3) | Missense Mutation (SNP) | VAF 100/289 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, varscan2
- KDM4A | c.1598G>T p.C533F | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- KDM5C | c.1285G>C p.V429L | Missense Mutation (SNP) | VAF 95/430 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KIAA2012 | c.2336C>A p.P779Q | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- KIDINS220 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 143/563 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- KIF24 | c.1386G>T p.R462S | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- KLHL33 | c.322T>G p.C108G | Missense Mutation (SNP) | VAF 82/414 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KLRF2 | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- KMT2A | c.9604A>T p.S3202C | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- KNDC1 | c.3777G>A p.M1259I | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- KRTAP10-7 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- LAIR1 | c.771G>A p.W257* | Nonsense Mutation (SNP) | VAF 48/188 reads (26%) | called by muse, varscan2
- LAMA2 | c.2876A>T p.Q959L | Missense Mutation (SNP) | VAF 168/831 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- LHPP | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 84/355 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- LIPN | c.601C>G p.P201A | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC14B | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- LRRC40 | c.1175G>C p.R392T | Missense Mutation (SNP) | VAF 46/369 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRC71 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- LRRTM4 | c.890T>G p.V297G | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- MAD1L1 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MDN1 | c.12032A>G p.E4011G | Missense Mutation (SNP) | VAF 42/650 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2
- MEF2D | c.382T>A p.F128I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- MEMO1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGAM2 | c.5899A>G p.N1967D | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated, low confidence (0.23); called by muse, mutect2
- MME | c.1914+2T>A p.X638_splice | Splice Site (SNP) | VAF 150/724 reads (21%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MRPL43 | c.94A>C p.S32R | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPS30 | c.919A>T p.R307* | Nonsense Mutation (SNP) | VAF 83/494 reads (17%) | called by muse, mutect2, varscan2
- MTRR | c.883A>G p.T295A (on ENST00000264668; = p.T268A on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 233/822 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MUC16 | c.37697C>G p.S12566C | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MUC19 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MUC5B | c.14603C>A p.S4868Y | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- MXD4 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MYO1D | c.1539-2A>T p.X513_splice | Splice Site (SNP) | VAF 45/126 reads (36%) | called by muse, mutect2, varscan2
- MYO7B | c.3752T>G p.L1251R | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYT1L | c.2277+1G>T p.X759_splice | Splice Site (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- NADSYN1 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAT10 | c.1263del p.S422Hfs*6 | Frame Shift Del (DEL) | VAF 61/248 reads (25%) | called by mutect2, pindel, varscan2
- NAV3 | c.2739C>A p.N913K | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NBEAL1 | c.2879T>C p.L960P | Missense Mutation (SNP) | VAF 116/462 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NCBP3 | c.1667A>G p.K556R | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.027); called by muse, varscan2
- NCF2 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NEU2 | c.690G>T p.R230S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NGEF | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 141/563 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOL9 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- NR5A2 | c.85C>A p.H29N | Missense Mutation (SNP) | VAF 75/415 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXPE4 | c.553dup p.S185Kfs*2 | Frame Shift Ins (INS) | VAF 63/295 reads (21%) | called by mutect2, pindel, varscan2
- OR10J1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 84/480 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- OR56B1 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 119/566 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5M3 | c.617C>A p.T206K | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); called by muse, mutect2
- PAK4 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PCDHGA9 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PCLO | c.5185A>T p.T1729S | Missense Mutation (SNP) | VAF 66/401 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PHKA1 | c.2785A>T p.T929S | Missense Mutation (SNP) | VAF 114/516 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PHRF1 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIGG | c.1529G>T p.G510V (on ENST00000453061 / NM_001127178.3; = p.G502V on NM_017733.4) | Missense Mutation (SNP) | VAF 175/612 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PIK3R1 | c.1477dup p.I493Nfs*3 (on ENST00000521381 / NM_181523.3; = p.I223Nfs*3 on NM_181504.4) | Frame Shift Ins (INS) | VAF 29/154 reads (19%) | called by mutect2, pindel, varscan2
- PKNOX1 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PLCB1 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 93/545 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR1A | c.5125G>T p.G1709W | Missense Mutation (SNP) | VAF 78/481 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POM121L12 | c.601T>A p.S201T | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PON3 | c.637A>C p.K213Q | Missense Mutation (SNP) | VAF 107/533 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- POP4 | c.333G>T p.R111S | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- POTEI | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- PPFIA4 | c.566C>G p.A189G | Missense Mutation (SNP) | VAF 66/344 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PPME1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRG3 | c.506G>T p.W169L | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRODH2 | c.1611G>T p.*537Yext*3 (on ENST00000301175; = p.*461Yext*3 on NM_021232.2 and 3 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- PRSS41 | c.665A>T p.Q222L | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PSG3 | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 72/393 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- PTH2R | c.1143C>G p.C381W | Missense Mutation (SNP) | VAF 64/502 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- PTPN4 | c.1907A>C p.D636A | Missense Mutation (SNP) | VAF 33/352 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.04); called by muse, mutect2
- RAI2 | c.1062G>C p.E354D | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASGRF1 | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RBM26 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RDH14 | c.905A>T p.Y302F | Missense Mutation (SNP) | VAF 110/491 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RELN | c.6989T>C p.L2330P | Missense Mutation (SNP) | VAF 154/707 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RGP1 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- RGS22 | c.3475C>G p.Q1159E | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RGS7 | c.491G>T p.W164L | Missense Mutation (SNP) | VAF 113/738 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RHEB | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 91/453 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RNPS1 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 74/414 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ROBO4 | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK1 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 20/403 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2
- ROR2 | c.2507A>T p.N836I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RP1 | c.4870A>G p.N1624D | Missense Mutation (SNP) | VAF 76/371 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- RUNDC3B | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 70/385 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- RXFP3 | c.161T>G p.L54R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- RYR2 | c.5141A>T p.Y1714F | Missense Mutation (SNP) | VAF 72/342 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- RYR3 | c.5827G>T p.E1943* | Nonsense Mutation (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2
- SACS | c.10542G>T p.K3514N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- SALL1 | c.2627del p.G876Afs*10 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, varscan2
- SDF4 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SEC23A | c.539G>A p.C180Y | Missense Mutation (SNP) | VAF 104/358 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SIPA1L1 | c.2587G>T p.V863F | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SIRPA | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 58/472 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SIRPB2 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 126/565 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC11A2 | c.851A>T p.Q284L (on ENST00000394904 / NM_001379455.1; = p.Q255L on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/470 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- SLC17A8 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC24A1 | c.649A>T p.R217W | Missense Mutation (SNP) | VAF 185/494 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SLC24A5 | c.743T>C p.M248T | Missense Mutation (SNP) | VAF 143/754 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SLC35C2 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 97/431 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SLC6A11 | c.488C>A p.T163N | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SMARCA5 | c.102A>T p.K34N | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SMARCD1 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 102/466 reads (22%) | called by muse, mutect2, varscan2
- SMPD1 | c.1035A>C p.E345D | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- SNRPN | c.686-1G>T p.X229_splice | Splice Site (SNP) | VAF 53/431 reads (12%) | called by muse, mutect2, varscan2
- SNX29 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 168/665 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SORCS3 | c.999del p.H333Qfs*73 | Frame Shift Del (DEL) | VAF 71/365 reads (19%) | called by mutect2, pindel, varscan2
- SPOCD1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SSRP1 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STIM2 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- STXBP2 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SUZ12 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | called by muse, varscan2
- TAAR8 | c.449T>A p.I150N | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- TBC1D17 | c.1027A>T p.K343* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- TDRD9 | c.1312T>C p.Y438H | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TECPR2 | c.3097G>C p.V1033L | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- TG | c.7648G>C p.E2550Q | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TGDS | c.626A>T p.K209I | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TIMM23 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR7 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TMCC3 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM132D | c.2968G>T p.A990S | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TREML4 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TRIM42 | c.118T>A p.F40I | Missense Mutation (SNP) | VAF 99/579 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- TRMT44 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TRPM1 | c.1026C>A p.V342= | Splice Region (SNP) | VAF 257/798 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.63737C>A p.S21246Y (on ENST00000591111; = p.S13822Y on NM_003319.4) | Missense Mutation (SNP) | VAF 19/167 reads (11%) | PolyPhen benign (0.323); called by muse, mutect2, varscan2
- USP9X | c.7264C>T p.L2422F | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- YES1 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBED8 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZC3H11A | c.767A>T p.N256I | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ZC3H12B | c.1799A>G p.N600S | Missense Mutation (SNP) | VAF 69/324 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZEB1 | c.147T>A p.D49E | Missense Mutation (SNP) | VAF 147/748 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZGLP1 | c.793C>A p.L265M | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- ZMYM1 | c.2095A>T p.T699S | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ZNF181 | c.1160G>T p.C387F | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2
- ZNF214 | c.41G>T p.W14L | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, varscan2
- ZNF780B | c.2155C>G p.H719D | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ABCA1 | c.1926C>G p.L642= | Silent (SNP) | VAF 72/395 reads (18%) | called by muse, mutect2, varscan2
- ABCC8 | c.2151C>T p.C717= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs776027296, CM062385; called by muse, mutect2, varscan2
- ACTL8 | c.111G>A p.P37= | Silent (SNP) | VAF 83/416 reads (20%) | catalogued as rs371845115, COSV64862461; called by muse, mutect2, varscan2
- ADGRL2 | c.3906G>C p.V1302= (on ENST00000370717 / NM_001366005.1; = p.V1246= on NM_012302.4) | Silent (SNP) | VAF 77/436 reads (18%) | called by muse, mutect2, varscan2
- APBA2 | c.1209G>T p.R403= | Silent (SNP) | VAF 103/717 reads (14%) | called by muse, mutect2, varscan2
- APTX | c.471A>T p.A157= | Silent (SNP) | VAF 86/425 reads (20%) | called by muse, mutect2, varscan2
- ARNT | c.1143G>C p.V381= | Silent (SNP) | VAF 48/212 reads (23%) | called by muse, mutect2, varscan2
- ASXL3 | c.2571T>C p.S857= | Silent (SNP) | VAF 110/630 reads (17%) | called by muse, mutect2, varscan2
- ATP1A4 | c.1053C>T p.C351= | Silent (SNP) | VAF 57/218 reads (26%) | called by muse, varscan2
- B3GAT2 | c.639T>C p.G213= | Silent (SNP) | VAF 24/140 reads (17%) | called by muse, varscan2
- BRINP2 | c.114G>T p.A38= | Silent (SNP) | VAF 60/352 reads (17%) | called by muse, mutect2, varscan2
- CA8 | c.570G>A p.Q190= | Silent (SNP) | VAF 94/491 reads (19%) | catalogued as COSV100526698, COSV100527094; called by muse, mutect2, varscan2
- CAD | c.6147C>T p.V2049= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as rs150228828; called by muse, varscan2
- CAPG | c.246G>C p.V82= | Silent (SNP) | VAF 84/463 reads (18%) | called by muse, mutect2, varscan2
- CAPN10 | c.1290G>T p.R430= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- CASP5 | c.117G>T p.V39= | Silent (SNP) | VAF 36/251 reads (14%) | called by muse, mutect2, varscan2
- CAVIN2 | c.1014C>T p.S338= | Silent (SNP) | VAF 30/446 reads (7%) | catalogued as rs760404586, COSV58425183; called by muse, mutect2
- CD83 | c.501G>T p.R167= | Silent (SNP) | VAF 134/262 reads (51%) | catalogued as COSV64788166; called by muse, mutect2, varscan2
- CDKL4 | c.9G>A p.K3= | Silent (SNP) | VAF 18/175 reads (10%) | catalogued as rs149237225; called by muse, mutect2, varscan2
- CENPQ | c.465G>T p.L155= | Silent (SNP) | VAF 63/169 reads (37%) | called by muse, mutect2, varscan2
- CHD5 | c.5658C>T p.P1886= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs774782723; called by muse, mutect2, varscan2
- CHRM2 | c.1293C>A p.I431= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as COSV100280800, COSV57781589; called by muse, mutect2, varscan2
- CHRND | c.297T>C p.S99= | Silent (SNP) | VAF 44/365 reads (12%) | called by muse, mutect2, varscan2
- CLDN22 | c.180G>A p.V60= | Silent (SNP) | VAF 107/398 reads (27%) | called by muse, mutect2, varscan2
- CLEC4D | c.63G>T p.S21= | Silent (SNP) | VAF 118/488 reads (24%) | catalogued as COSV100223037; called by muse, mutect2, varscan2
- CUTA | c.240C>T p.V80= (on ENST00000488034 / NM_001014840.2; = p.V57= on NM_015921.3) | Silent (SNP) | VAF 48/161 reads (30%) | called by muse, mutect2, varscan2
- CXCR2 | c.670C>T p.L224= | Silent (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- DEUP1 | c.1287A>G p.L429= | Silent (SNP) | VAF 35/201 reads (17%) | called by muse, mutect2, varscan2
- DNAH6 | c.7335T>A p.L2445= | Silent (SNP) | VAF 132/492 reads (27%) | catalogued as COSV52887824; called by muse, mutect2, varscan2
- EDEM2 | c.78C>T p.D26= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs199925808, COSV100993630; called by muse, mutect2, varscan2
- EID2B | c.6G>T p.A2= | Silent (SNP) | VAF 56/337 reads (17%) | catalogued as COSV100410968; called by muse, mutect2, varscan2
- EML6 | c.3708G>A p.G1236= | Silent (SNP) | VAF 66/336 reads (20%) | catalogued as rs1250478339; called by muse, mutect2, varscan2
- EN1 | c.234C>A p.P78= | Silent (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- EP400 | c.1536C>T p.T512= | Silent (SNP) | VAF 17/238 reads (7%) | catalogued as rs989992054; called by muse, mutect2
- EP400 | c.5523G>A p.R1841= | Silent (SNP) | VAF 92/450 reads (20%) | catalogued as rs781254068; called by muse, mutect2, varscan2
- ETV3L | c.553C>A p.R185= | Silent (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- FAM135B | c.3694C>A p.R1232= | Silent (SNP) | VAF 68/419 reads (16%) | catalogued as COSV52706786; called by muse, mutect2, varscan2
- FBXL16 | c.867G>C p.T289= | Silent (SNP) | VAF 31/163 reads (19%) | catalogued as rs1246436168; called by muse, mutect2, varscan2
- FMN2 | c.237G>A p.R79= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as rs1375418532, COSV60425828, COSV60428498; called by muse, varscan2
- FOXI1 | c.366G>C p.V122= | Silent (SNP) | VAF 95/355 reads (27%) | called by muse, mutect2, varscan2
- FOXO6 | c.1338C>G p.L446= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as rs1272366857; called by muse, mutect2, varscan2
- FRMD1 | c.718C>T p.L240= | Silent (SNP) | VAF 40/223 reads (18%) | catalogued as COSV51961616; called by muse, mutect2, varscan2
- FZD7 | c.1380G>A p.K460= | Silent (SNP) | VAF 107/495 reads (22%) | catalogued as COSV53808939; called by muse, mutect2, varscan2
- GABRA5 | c.522C>T p.P174= | Silent (SNP) | VAF 193/647 reads (30%) | called by muse, mutect2, varscan2
- GATA3 | c.1323C>T p.A441= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV60521781; called by muse, mutect2
- GDPD4 | c.1620C>A p.P540= | Silent (SNP) | VAF 62/438 reads (14%) | catalogued as COSV100265143; called by muse, mutect2, varscan2
- GNG2 | c.6C>A p.A2= | Silent (SNP) | VAF 37/166 reads (22%) | called by muse, mutect2, varscan2
- GPR78 | c.579C>G p.L193= | Silent (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- GRM5 | c.1980A>T p.S660= | Silent (SNP) | VAF 41/357 reads (11%) | called by muse, mutect2, varscan2
- GRM7 | c.1497A>T p.T499= | Silent (SNP) | VAF 103/300 reads (34%) | called by muse, mutect2, varscan2
- HLX | c.852C>T p.S284= | Silent (SNP) | VAF 46/217 reads (21%) | called by muse, mutect2, varscan2
- IDUA | c.642C>T p.P214= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as COSV99926147; called by muse, mutect2, varscan2
- IGHV3-23 | c.315G>C p.L105= | Silent (SNP) | VAF 52/328 reads (16%) | called by muse, varscan2
- IGKV1D-43 | c.33G>C p.G11= | Silent (SNP) | VAF 53/414 reads (13%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.603C>A p.I201= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as rs746730581, COSV61147519; called by muse, mutect2, varscan2
- IL9R | c.1161G>A p.L387= | Silent (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- IMPG1 | c.1398T>C p.D466= | Silent (SNP) | VAF 82/499 reads (16%) | called by muse, mutect2, varscan2
- IQCG | c.234G>A p.L78= | Silent (SNP) | VAF 104/359 reads (29%) | catalogued as rs752253854; called by muse, mutect2, varscan2
- IRGC | c.228C>A p.G76= | Silent (SNP) | VAF 45/221 reads (20%) | called by muse, mutect2, varscan2
- IRGC | c.229C>T p.L77= | Silent (SNP) | VAF 46/224 reads (21%) | called by muse, mutect2, varscan2
- JAG1 | c.915G>A p.P305= | Silent (SNP) | VAF 130/520 reads (25%) | catalogued as rs371165309; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNU1 | c.3057C>A p.T1019= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- KIAA0586 | c.4506G>A p.V1502= (on ENST00000619416 / NM_001244190.2; = p.V1441= on NM_014749.5) | Silent (SNP) | VAF 54/223 reads (24%) | called by muse, mutect2, varscan2
- KIAA0825 | c.3081G>A p.E1027= | Silent (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- KIF19 | c.2325G>A p.L775= | Silent (SNP) | VAF 56/167 reads (34%) | called by muse, mutect2, varscan2
- KIF1A | c.1152C>T p.Y384= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs776874494, COSV100240157, COSV57506685; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHDC1 | c.723T>C p.N241= | Silent (SNP) | VAF 63/220 reads (29%) | called by muse, mutect2, varscan2
- LAMA3 | c.5943G>T p.R1981= (on ENST00000313654 / NM_198129.4; = p.R372= on NM_000227.6) | Silent (SNP) | VAF 85/394 reads (22%) | catalogued as rs141778665; called by muse, mutect2, varscan2
- LRRTM1 | c.804C>A p.I268= | Silent (SNP) | VAF 29/209 reads (14%) | catalogued as COSV54440785; called by muse, mutect2, varscan2
- MARCHF6 | c.2031A>T p.T677= | Silent (SNP) | VAF 203/590 reads (34%) | called by muse, mutect2, varscan2
- MDGA2 | c.1870C>A p.R624= (on ENST00000399232 / NM_001113498.2; = p.R326= on NM_182830.4) | Silent (SNP) | VAF 99/381 reads (26%) | catalogued as rs762439461, COSV62090758, COSV62105078; called by muse, mutect2, varscan2
- MED1 | c.933C>T p.I311= | Silent (SNP) | VAF 44/166 reads (27%) | called by muse, varscan2
- MPP4 | c.198A>G p.L66= | Silent (SNP) | VAF 55/272 reads (20%) | catalogued as COSV59634712; called by muse, mutect2, varscan2
- MROH2B | c.3444G>C p.V1148= | Silent (SNP) | VAF 76/240 reads (32%) | catalogued as COSV68186304; called by muse, mutect2, varscan2
- MTERF3 | c.744A>G p.P248= | Silent (SNP) | VAF 46/255 reads (18%) | called by muse, mutect2, varscan2
- MTRR | c.882G>T p.V294= (on ENST00000264668; = p.V267= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 236/819 reads (29%) | called by muse, mutect2, varscan2
- MYOD1 | c.213G>T p.P71= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- NALCN | c.1200G>T p.V400= | Silent (SNP) | VAF 70/404 reads (17%) | called by muse, mutect2, varscan2
- NEUROD6 | c.958C>T p.L320= | Silent (SNP) | VAF 71/314 reads (23%) | called by muse, mutect2, varscan2
- NLGN4X | c.459G>T p.V153= | Silent (SNP) | VAF 147/609 reads (24%) | called by muse, mutect2, varscan2
- NR4A1 | c.1680C>T p.P560= | Silent (SNP) | VAF 32/280 reads (11%) | catalogued as rs747538322; called by muse, mutect2, varscan2
- NSMCE2 | c.217C>A p.R73= | Silent (SNP) | VAF 38/237 reads (16%) | catalogued as COSV54894729; called by muse, mutect2, varscan2
- OPRK1 | c.990C>T p.Y330= | Silent (SNP) | VAF 93/497 reads (19%) | catalogued as rs77333617, COSV99653832; called by muse, mutect2, varscan2
- OR10P1 | c.300C>T p.A100= | Silent (SNP) | VAF 43/263 reads (16%) | called by muse, mutect2, varscan2
- OR10Q1 | c.144C>A p.A48= | Silent (SNP) | VAF 49/413 reads (12%) | catalogued as COSV57470453; called by muse, mutect2, varscan2
- OR2M3 | c.558C>A p.I186= | Silent (SNP) | VAF 63/284 reads (22%) | called by muse, mutect2, varscan2
- OR4C6 | c.684T>A p.S228= | Silent (SNP) | VAF 62/465 reads (13%) | called by muse, mutect2, varscan2
- OR51Q1 | c.768C>A p.P256= | Silent (SNP) | VAF 56/165 reads (34%) | called by muse, mutect2, varscan2
- OR52W1 | c.597C>A p.A199= | Silent (SNP) | VAF 62/418 reads (15%) | called by mutect2, varscan2
- OR6K2 | c.549G>T p.V183= | Silent (SNP) | VAF 59/277 reads (21%) | catalogued as rs1421845370; called by muse, mutect2, varscan2
- PCBP3 | c.201T>G p.T67= | Silent (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- PCDHGA11 | c.2307G>A p.L769= | Silent (SNP) | VAF 53/216 reads (25%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.1080G>T p.S360= | Silent (SNP) | VAF 69/298 reads (23%) | catalogued as COSV53957153; called by muse, mutect2, varscan2
- PCSK5 | c.3162A>G p.T1054= | Silent (SNP) | VAF 53/226 reads (23%) | called by muse, mutect2, varscan2
- PDE1A | c.969G>T p.V323= | Silent (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- PDZD2 | c.891A>T p.T297= | Silent (SNP) | VAF 93/323 reads (29%) | called by muse, mutect2, varscan2
- PITPNM3 | c.2892G>A p.A964= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- PITX2 | c.534C>T p.N178= (on ENST00000354925 / NM_001204397.1; = p.N185= on NM_000325.6) | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- PLA2G4C | c.36C>T p.L12= | Silent (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- PLCZ1 | c.193C>A p.R65= | Silent (SNP) | VAF 78/304 reads (26%) | catalogued as rs745955620, COSV56854741; called by muse, mutect2, varscan2
- PPP1R3F | c.201G>T p.A67= | Silent (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- PRDM9 | c.438G>A p.E146= | Silent (SNP) | VAF 48/436 reads (11%) | called by muse, mutect2, varscan2
- PRKRIP1 | c.63C>T p.L21= | Silent (SNP) | VAF 47/331 reads (14%) | catalogued as rs782789810, COSV100700321; called by muse, mutect2, varscan2
- PRPF6 | c.420G>A p.Q140= | Silent (SNP) | VAF 106/545 reads (19%) | called by muse, mutect2, varscan2
- PTCRA | c.516G>C p.L172= | Silent (SNP) | VAF 91/376 reads (24%) | called by muse, mutect2, varscan2
- PTPRK | c.276A>G p.R92= | Silent (SNP) | VAF 123/666 reads (18%) | called by muse, mutect2, varscan2
- RFX4 | c.960G>A p.L320= (on ENST00000392842 / NM_213594.3; = p.L226= on NM_032491.6) | Silent (SNP) | VAF 86/495 reads (17%) | called by muse, mutect2, varscan2
- RHPN2 | c.1173G>A p.E391= | Silent (SNP) | VAF 28/967 reads (3%) | called by muse, mutect2
- RNF181 | c.363C>T p.P121= | Silent (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- RRBP1 | c.3552A>G p.L1184= (on ENST00000377813 / NM_001365613.2; = p.L751= on NM_004587.3) | Silent (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- SCN3A | c.1947T>C p.D649= | Silent (SNP) | VAF 62/286 reads (22%) | called by muse, mutect2, varscan2
- STXBP2 | c.483G>T p.R161= | Silent (SNP) | VAF 46/223 reads (21%) | called by muse, mutect2, varscan2
- STXBP5L | c.2013A>T p.T671= | Silent (SNP) | VAF 118/689 reads (17%) | called by muse, mutect2, varscan2
- TEX13C | c.171G>T p.P57= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- TG | c.6945G>A p.P2315= | Silent (SNP) | VAF 116/642 reads (18%) | catalogued as rs769872031, COSV99601374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM132A | c.558G>T p.V186= | Silent (SNP) | VAF 60/337 reads (18%) | catalogued as COSV99137110; called by muse, varscan2
- TMEM135 | c.777C>T p.I259= | Silent (SNP) | VAF 94/402 reads (23%) | catalogued as COSV59704030; called by muse, mutect2, varscan2
- TMEM229B | c.27G>T p.A9= | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- TMEM252 | c.192C>T p.R64= | Silent (SNP) | VAF 66/306 reads (22%) | catalogued as COSV101051132; called by muse, mutect2, varscan2
- TRHR | c.768C>T p.S256= | Silent (SNP) | VAF 63/337 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.95106T>C p.S31702= (on ENST00000591111; = p.S24278= on NM_003319.4) | Silent (SNP) | VAF 52/611 reads (9%) | called by muse, mutect2
- UBE4A | c.2257A>C p.R753= (on ENST00000252108 / NM_001204077.2; = p.R760= on NM_004788.4) | Silent (SNP) | VAF 47/203 reads (23%) | called by muse, mutect2, varscan2
- UBIAD1 | c.702C>T p.T234= | Silent (SNP) | VAF 107/587 reads (18%) | catalogued as rs1210927908; called by muse, mutect2, varscan2
- UGT2A3 | c.129A>G p.L43= | Silent (SNP) | VAF 63/400 reads (16%) | called by muse, mutect2, varscan2
- XKR5 | c.1632C>T p.F544= | Silent (SNP) | VAF 32/195 reads (16%) | called by muse, mutect2, varscan2
- YIPF3 | c.646C>T p.L216= | Silent (SNP) | VAF 44/156 reads (28%) | called by muse, varscan2
- ZFYVE26 | c.3723G>T p.R1241= | Silent (SNP) | VAF 69/307 reads (22%) | called by muse, mutect2, varscan2
- ZNF521 | c.2481C>T p.H827= | Silent (SNP) | VAF 108/439 reads (25%) | called by muse, mutect2, varscan2
- ZNF536 | c.36G>T p.S12= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs141139128; called by muse, mutect2, varscan2
- ADCY5 | c.1135-15345T>C | Intron (SNP) | VAF 48/315 reads (15%) | called by muse, mutect2, varscan2
- AOAH | c.*49G>T | 3'UTR (SNP) | VAF 131/546 reads (24%) | called by muse, varscan2
- ATXN7L1 | c.2472+63C>G | Intron (SNP) | VAF 33/165 reads (20%) | called by muse, mutect2, varscan2
- BDNF | c.-21-15633G>T | Intron (SNP) | VAF 93/440 reads (21%) | called by muse, mutect2, varscan2
- BMS1P15 | n.354T>A | RNA (SNP) | VAF 80/577 reads (14%) | called by muse, mutect2, varscan2
- BOLL | c.553-1580T>C | Intron (SNP) | VAF 21/308 reads (7%) | catalogued as rs1039683668; called by muse, mutect2
- C10orf143 | c.69+4590C>T | Intron (SNP) | VAF 34/136 reads (25%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.-14-22C>T | Intron (SNP) | VAF 125/344 reads (36%) | catalogued as COSV100190118; called by muse, mutect2, varscan2
- CD55 | c.*5A>G | 3'UTR (SNP) | VAF 85/336 reads (25%) | called by muse, mutect2, varscan2
- CD96 | c.799+22A>C | Intron (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- CLEC18B | c.877+110G>T | Intron (SNP) | VAF 16/416 reads (4%) | called by muse, mutect2
- CUBN | c.-37G>T | 5'UTR (SNP) | VAF 106/556 reads (19%) | called by muse, varscan2
- DPYD | c.483+610G>T | Intron (SNP) | VAF 78/457 reads (17%) | called by muse, mutect2, varscan2
- DSC2 | c.*23A>G | 3'UTR (SNP) | VAF 88/399 reads (22%) | called by muse, mutect2, varscan2
- FAM71F1 | chr7:128714020 G>T | 5'Flank (SNP) | VAF 57/273 reads (21%) | catalogued as COSV100171081; called by muse, mutect2, varscan2
- FGFR1 | c.358+36A>T | Intron (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- FOXP3 | c.-22-709C>A | Intron (SNP) | VAF 64/279 reads (23%) | called by muse, mutect2, varscan2
- FRMD4B | c.417-5221A>G | Intron (SNP) | VAF 30/120 reads (25%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.2189A>G | RNA (SNP) | VAF 35/928 reads (4%) | called by muse, mutect2
- HCCS | c.522-867T>C | Intron (SNP) | VAF 39/124 reads (31%) | catalogued as rs1490227898; called by muse, mutect2, varscan2
- HEPACAM | c.-32G>T | 5'UTR (SNP) | VAF 64/324 reads (20%) | called by muse, mutect2, varscan2
- HOATZ | c.339+8806C>G | Intron (SNP) | VAF 36/260 reads (14%) | called by muse, mutect2, varscan2
- HSP90B3P | n.639C>T | RNA (SNP) | VAF 60/413 reads (15%) | called by muse, mutect2, varscan2
- HUWE1 | c.1490-676_1490-675del | Intron (DEL) | VAF 85/431 reads (20%) | called by mutect2, pindel, varscan2
- KIF1B | c.2115+6517C>T | Intron (SNP) | VAF 117/586 reads (20%) | catalogued as rs1486163340; called by muse, mutect2, varscan2
- MFSD4B | c.*469C>T | 3'UTR (SNP) | VAF 106/475 reads (22%) | catalogued as rs1289725412; called by muse, mutect2, varscan2
- MS4A6A | c.-170G>T | 5'UTR (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- NDUFAF1 | c.-213A>G | 5'UTR (SNP) | VAF 106/336 reads (32%) | catalogued as rs1279832635; called by muse, mutect2, varscan2
- NOVA1 | c.137-416G>T | Intron (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2
- NRXN1 | c.833-32791C>A | Intron (SNP) | VAF 62/220 reads (28%) | called by muse, mutect2, varscan2
- NXF3 | c.-6G>A | 5'UTR (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2, varscan2
- P3H4 | c.-189G>T | 5'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, varscan2
- PCMTD1 | c.*2485C>T | 3'UTR (SNP) | VAF 75/770 reads (10%) | catalogued as rs1188948462; called by muse, mutect2
- PCYT1A | c.708+347C>T | Intron (SNP) | VAF 30/526 reads (6%) | called by muse, mutect2
- PTPRU | c.-53C>G | 5'UTR (SNP) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- RALGAPA2 | c.2203+2952A>T | Intron (SNP) | VAF 52/279 reads (19%) | called by muse, mutect2, varscan2
- RERG | c.62-16719A>G | Intron (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- RN7SL759P | chr15:20570804 A>T | 5'Flank (SNP) | VAF 282/2463 reads (11%) | called by muse, mutect2, varscan2
- RNU1-5P | chr1:16871069 C>A | 5'Flank (SNP) | VAF 21/362 reads (6%) | called by muse, mutect2
- RNU6-713P | chr12:40550126 A>G | 3'Flank (SNP) | VAF 47/318 reads (15%) | called by muse, mutect2, varscan2
- SEPTIN6 | chrX:119616704 T>C | 3'Flank (SNP) | VAF 66/260 reads (25%) | called by muse, mutect2, varscan2
- SMOC2 | c.1323+698C>T | Intron (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- SNORD116-10 | chr15:25077049 C>A | 3'Flank (SNP) | VAF 80/373 reads (21%) | called by muse, mutect2, varscan2
- SOX8 | chr16:979690 T>A | 5'Flank (SNP) | VAF 77/415 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.4286C>A | RNA (SNP) | VAF 48/282 reads (17%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-99_-98insAACA | 5'UTR (INS) | VAF 20/124 reads (16%) | called by pindel, varscan2
- STMN2 | c.*14C>A | 3'UTR (SNP) | VAF 62/300 reads (21%) | called by muse, varscan2
- SVIL2P | n.1715C>A | RNA (SNP) | VAF 41/312 reads (13%) | called by muse, mutect2, varscan2
- TRMT61A | c.-92G>T | 5'UTR (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- TTC9C | chr11:62728457 G>A | 5'Flank (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.9988+48G>T | Intron (SNP) | VAF 33/229 reads (14%) | called by muse, mutect2, varscan2
- UMPS | c.*4562T>G | 3'UTR (SNP) | VAF 68/277 reads (25%) | called by muse, mutect2, varscan2
- VPS13A | c.100+46G>C | Intron (SNP) | VAF 14/164 reads (9%) | catalogued as rs745374094; called by muse, mutect2
- WASH8P | n.1126C>T | RNA (SNP) | VAF 60/1717 reads (3%) | catalogued as rs781819174; called by muse, mutect2
- ZBP1 | c.1094-2417T>A | Intron (SNP) | VAF 73/437 reads (17%) | called by muse, mutect2, varscan2
- ZNF733P | n.453del | RNA (DEL) | VAF 14/80 reads (18%) | called by mutect2, varscan2
